Gene-level copy-number profile of tumor specimen TCGA-GU-AATO-01A from TCGA case TCGA-GU-AATO, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 75.8 years (27,684 days).
Specimen TCGA-GU-AATO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.0aeed974-9ad8-4208-9c09-43418386665f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GU-AATO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0991f8bb-602f-4ca3-bade-0f1de7e5d4b1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 139; copy number 2: 20,641; copy number 3: 12,453; copy number 4: 18,731; copy number 5: 3,727; copy number 6: 2,458; copy number 7: 1,109; copy number 8: 409; copy number 9: 149.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GU-AATO-01A-11D-A390-01): tumor purity 0.52, ploidy 3.23, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 149 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:68,921,248–69,437,628, 12 genes, copy number 9: GKN3P, GKN2, GKN1, ANTXR1, AC114802.1, MIR3126, RNA5SP96, RNU6-1216P, AC112230.1, GFPT1, Y_RNA, NFU1.
- chr14:22,773,222–26,143,305, 137 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 136. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
